CGCI case HTMCP-03-06-02071 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/472ab66f-936b-4a90-aa75-a601845b9ec8

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 43 years; Vital status: Dead; Days to death: 133 days.

Diagnoses (1)
1. Primary of the cervix uteri (histology not recorded by GDC). Site of resection or biopsy: Cervix uteri; Age at diagnosis: 43.4 years (15,842 days); Year of diagnosis: 2014; Method of diagnosis: Biopsy; AJCC clinical T: T2a2; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IIA2; FIGO staging edition year: 2009; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 133 days.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 70; ECOG performance status: 2.
- Follow-up contact recording only the day: day 133.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Risk factors: HIV/AIDS.
- Day 0: Pregnancy outcome: Miscarriage.
- Day 0: Comorbidities: HIV/AIDS.
- Day 0: Weight: 55.3 kg; Height: 169.5 cm; BMI: 19.2; CD4 count: 233; Haart treatment indicator: No; HIV viral load: 27810; Hormonal contraceptive use: Former User; Hysterectomy type: Not Performed; Menopause status: Premenopausal; Pregnant at diagnosis: No.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02071-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02071-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02071-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 6; Pregnancies count miscarriage: 1; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 7; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Haart therapy at diagnosis: No; Haart therapy prior to diagnosis: No.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02071-01A-01R-4427:
- % tumour top: 55
- % tumour bottom: 55

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02071-01A-01D-4427:
- % tumour top: 55
- % tumour bottom: 55

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02071-10A-01D-4427:
- % tumour top: 0
- % tumour bottom: 0
